Gene-level copy-number profile of tumor specimen TCGA-FJ-A3ZE-01A from TCGA case TCGA-FJ-A3ZE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.3 years (23,866 days).
Specimen TCGA-FJ-A3ZE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fd7f475a-7c45-4e5b-8e9b-01e035ec0225.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FJ-A3ZE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a289108f-5b8f-459e-9760-dff0006f4992

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 18,584; copy number 2: 35,245; copy number 3: 5,010; copy number 4: 378; copy number 5: 563.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FJ-A3ZE-01A-11D-A23L-01): tumor purity 0.96, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,856,389–60,856,605, 1 gene: U3.
- chr4:112,285,509–112,739,106, 19 genes (within-gene range 0–2): ALPK1, RTEL1P1, TOX4P1, NEUROG2, NEUROG2-AS1, RPL23AP94, ZGRF1, H3P14, LARP7, MIR302CHG, MIR367, MIR302D, MIR302A, MIR302C, MIR302B, OSTCP4, AC106864.1, WRBP1, AC017007.3.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 11 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr13:46,717,423–46,717,688, 1 gene: AL359880.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 563 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:18,954,943–40,518,736, 282 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:37,326,575–38,704,855, 54 genes, copy number 5: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr8:38,744,020–38,744,131, 1 gene, copy number 5: Y_RNA.
- chr8:38,988,808–39,867,812, 13 genes, copy number 5: TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1.
- chr19:6,887,566–10,869,790, 213 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,169. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
